Gene-level copy-number profile of tumor specimen TCGA-FS-A1ZU-06A from TCGA case TCGA-FS-A1ZU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.3 years (26,400 days).
Specimen TCGA-FS-A1ZU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.46de5afe-f6e6-4e93-b0cd-2e8d99abe139.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A1ZU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e4c46ec-8b4a-43dd-98ff-d0103984a0e8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 11,285; copy number 3: 27,677; copy number 4: 9,503; copy number 5: 8,713; copy number 6: 682; copy number 8: 564; copy number 9: 1,014; copy number 10: 63; copy number 11: 203; copy number 12: 48; copy number 13: 18; copy number 14: 5; copy number 15: 1; copy number 23: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A1ZU-06A-12D-A194-01): tumor purity 0.95, ploidy 3.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,947 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,006,309–149,026,269, 2 genes, copy number 9: AC239802.1, AC239802.2.
- chr1:193,012,250–204,213,988, 209 genes, copy number 9–11 (within-gene range 5–11) (broad region; genes not listed).
- chr1:204,276,901–204,280,363, 1 gene, copy number 11: AL592114.3.
- chr1:204,422,628–206,023,909, 49 genes, copy number 13–23: PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, AC119673.1, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1, RAB7B, CTSE.
- chr1:245,749,342–246,931,948, 25 genes, copy number 11 (within-gene range 5–11): SMYD3, AC118555.1, SMYD3-AS1, CHCHD4P5, RNU6-1283P, SMYD3-IT1, Y_RNA, AL356583.1, LINC01743, AL356583.3, AL356583.2, TFB2M, CNST, AL591623.1, AL591623.2, AL591848.2, AL591848.1, SCCPDH, RPL35AP6, KIF28P, AL591848.3, LINC01341, AC113174.1, AC113174.2, AHCTF1.
- chr1:247,840,928–247,880,138, 2 genes, copy number 13–15 (within-gene range 5–15): OR11L1, TRIM58.
- chr3:142,654,784–142,673,904, 2 genes, copy number 10: PLS1-AS1, RN7SKP25.
- chr3:147,276,768–147,510,293, 4 genes, copy number 13: RPL21P71, ZIC4, ZIC4-AS1, ZIC1.
- chr3:157,234,580–157,235,149, 1 gene, copy number 11: AC092944.3.
- chr3:157,543,246–157,677,749, 2 genes, copy number 10 (within-gene range 3–10): SLC66A1L, AC084212.1.
- chr7:134,284,500–134,998,153, 12 genes, copy number 11 (within-gene range 3–11): AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15, BPGM, AC009276.1, TUBB3P2, CALD1, AC083870.1.
- chr7:138,404,195–138,442,238, 2 genes, copy number 10: PTMAP10, IMPDH1P3.
- chr7:141,074,064–142,288,869, 37 genes, copy number 12 (within-gene range 2–12): TMEM178B, AC006362.1, NDUFB10P2, AC005692.3, AC005692.1, AC005692.2, AC073878.1, AC073878.2, AGK, AC004918.1, DENND11, AC004918.3, WEE2-AS1, WEE2, RNU1-82P, SSBP1, TAS2R3, TAS2R4, TAS2R6P, TAS2R5, MTCO1P55, MTND2P5, MTND1P3, MYL6P4, PRSS37, OR9A3P, OR9A1P, MGAM, OR9N1P, OR9A4, CLEC5A, TAS2R38, MGAM2, MOXD2P, PRSS58, TRY2P, AC245088.1.
- chr7:146,116,002–148,420,998, 1 gene, copy number 12 (within-gene range 2–12): CNTNAP2.
- chr7:146,311,720–149,734,575, 53 genes, copy number 10–12: Y_RNA, CNTNAP2-AS1, DUTP3, RANP2, MIR548F4, AC005518.1, AC005518.2, RNU6-1184P, RNA5SP249, RN7SL456P, U3, RN7SL72P, AC083849.1, AC006974.1, AC006974.2, AC005229.2, AC005229.5, C7orf33, AC005229.1, AC005229.3, AC005229.4, CUL1, EZH2, RNU7-20P, Metazoa_SRP, RN7SL569P, AC073140.2, AC073140.1, RNY4, RNY3, RNY1, GHET1, PDIA4, RNU6-650P, COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746, ZNF767P, KRBA1.
- chr7:157,539,056–158,587,823, 1 gene, copy number 9 (within-gene range 2–9): PTPRN2.
- chr7:157,987,169–158,830,253, 10 genes, copy number 9 (within-gene range 1–9): AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 8–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
